Surgical pathology report (de-identified scan), TCGA case TCGA-D5-5537, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-5537-01A (Primary Tumor).

Examination: Histopathological examination

Material: Multiple organ resection – segment of the large intestine

Unit in charge: Central Operating Theatre

Physician in charge:

Material collected on: Material received on:

Expected time of examination: up to

Clinical diagnosis: Cancer of the large intestine

TCGA – D5 – 5537

Examination performed on

Macroscopic description:

19.9 cm length of the large intestine, with periintestinal tissue sized 25 x 13 x 3cm, 8 cm segment of the small intestine, and 7 cm appendix.

Cauliflower-shaped tumour in the intestinal mucosa, sized 4.7 x 9.3 x 1.2 cm.

The lesion surrounds 100% of the intestine circumference, 9.2 cm from the proximal cut end, 12.2 cm from the distal cut end, and 1.2 cm from the ileocecal valve.

Tumour accompanied by polyps of up to 1.5 cm.

Microscopic description:

Adenocarcinoma tubuloapillare partim mucinosum (G3).

Infiltratio carcinomatosa profunda tunicae muscularis propriae et telae adiposae pericolicae.

Intestine ends free of neoplastic lesions.

Off tumour: Adenomata tubulopapillaria cum dysplasia gradus mediocris ad maiorem.

Lymphonodulitis reactiva (No VII).

Processus vermicularis sine laesionibus.

Histopathological diagnosis:

Adenocarcinoma tubulopapillare partim mucinosum coll.

(G3; DukesB; Astler-CollerB2; pT3; pNO).

Adenomata tubulopapillaria cum dysplasia gradus mediocris ad maiorem (high grade).

Source: NCI Genomic Data Commons file d1d87fc7-6e79-47de-b942-4958bebd131e (TCGA-D5-5537.2674F1EC-C290-426E-8394-42DB0E7EC94A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).